Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACZ-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
JW 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Central bisectionectomy

Organ: Liver (15.0 x 11.0 x 5.5 cm, 477.0 gm)

Gallbladder (8.0 cm in length, 3.0 cm in diameter)

[Liver]

Lesions: Huge hepatic mass

- Size: 8.8 x 7.5 x 6.8 cm

- Cut surface: Relatively well-demarcated, yellowish tan, round and solid

- Gross type: Multinodular confluent

- Extent: Confined to the capsule, grossly

- Resection margin: Not involved, grossly (safety margin: 0.5 cm)

Remaining parenchyme: Unremarkable, grossly

[Gallbladder]

Serosal surface: Yellowish green and smooth

Mucosal surface: Dark green and velvety, no mural nodule

Wall: 0.2 cm in thickness

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, mass of liver x 4

RM, tumor with resection margin x 1

L, nontumorous liver parenchyme x 1

LN, labeled as '12' x 1

GB1-2, gallbladder x 2

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

The worst differentiation IV

The major differentiation IV

Histologic type: Trabecular and tubular

Cell type: Hepatic

Fatty change: No

Cholangiocarcinoma: No

Fibrous capsule formation: Yes

Capsular infiltration with gallbladder invasion: Yes

Septum formation: Yes

[page 2 of 2]
Surgical resection margin invasion: Very close to resection margin (less than 0.1 cm)

Serosal invasion: No

Portal vein invasion: No

Vascular invasion: Yes

Bile duct invasion: No

NOT reported. Gross:

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

liver,ectomy,hepatocellular carcinoma

T56000, P10, M81703

gallbladder,ectomy,direct tumor extension,lymphovascular emboli from liver present

T57000, P10, MDTE, lymphovascular emboli from liver present

lymph node,biopsy,no tumor

T08000, P50, M09450

DIAGNOSIS:

Liver, segment 4, 5, and 8, central bisectionectomy:

Hepatocellular carcinoma

Gallbladder, cholecystectomy:

Direct tumor extension from liver

Lymphovascular emboli from liver present

Lymph node, '12', biopsy:

No tumor present (0/1)

Suggestion :

Source: NCI Genomic Data Commons file a751d949-f546-49a1-8d8e-0cbe4d0e6e37 (TCGA-DD-AACZ.8A8CB301-B3F2-469B-85D3-CAEA5A2F46ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).